Somatic mutation profile of tumor specimen MP2PRT-PAUUDV-TMP1-A (aliquot MP2PRT-PAUUDV-TMP1-A-1-0-D-A79Q-36) from MP2PRT case MP2PRT-PAUUDV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.1 years (2,231 days).
Specimen MP2PRT-PAUUDV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) faa6e246-be9a-4b1a-98bc-07a96e68c46b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUUDV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUUDV-NB1-A-1-0-D-A79Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4382f68b-a629-4a7a-8c9a-0780957b3da9

The open-access MAF lists 16 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, Nonsense Mutation 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 109/308 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MPST | c.116C>T p.P39L (on ENST00000341116 / NM_001369904.2; = p.P59L on NM_021126.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 256/653 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1011808569; called by muse, mutect2, varscan2
- TULP4 | c.1336C>T p.R446C | Missense Mutation (SNP) | VAF 201/444 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1333534414; called by muse, mutect2, varscan2
- COPS2 | c.1168G>A p.V390M | Missense Mutation (SNP) | VAF 93/245 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FRAS1 | c.5329A>G p.N1777D | Missense Mutation (SNP) | VAF 21/291 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); called by muse, mutect2
- IDH3G | c.956A>G p.N319S | Missense Mutation (SNP) | VAF 167/331 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- MED12 | c.2366A>G p.E789G | Missense Mutation (SNP) | VAF 123/429 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- NUP160 | c.2702G>A p.W901* | Nonsense Mutation (SNP) | VAF 114/310 reads (37%) | called by muse, mutect2, varscan2
- SYNCRIP | c.1618G>A p.G540R | Missense Mutation (SNP) | VAF 179/455 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TNC | c.1669G>T p.D557Y | Missense Mutation (SNP) | VAF 207/553 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- FAM120C | c.2763C>T p.L921= | Silent (SNP) | VAF 346/703 reads (49%) | called by muse, mutect2
- MYO1D | c.2268C>T p.Y756= | Silent (SNP) | VAF 148/364 reads (41%) | catalogued as rs150683059; called by muse, mutect2, varscan2
- ROCK1 | c.3690G>A p.E1230= | Silent (SNP) | VAF 39/440 reads (9%) | catalogued as rs1568365779; called by muse, mutect2
- UNC80 | c.4764C>T p.Y1588= | Silent (SNP) | VAF 134/336 reads (40%) | catalogued as rs773020190; called by muse, varscan2
- NXF5 | n.960G>A | RNA (SNP) | VAF 24/139 reads (17%) | catalogued as rs377703112; called by muse, mutect2, varscan2
- SPPL2B | c.956+25C>T | Intron (SNP) | VAF 89/238 reads (37%) | catalogued as rs749910990; called by muse, mutect2, varscan2
